Somatic mutation profile of tumor specimen 944793e9-96c2-4820-abb8-8f72f6 (aliquot 944793e9-96c2-4820-abb8-8f72f6_D6) from CPTAC case 11BR003, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 53.5 years (19,527 days).
Specimen 944793e9-96c2-4820-abb8-8f72f6: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b61643fe-6882-4462-a011-ef17467eb48e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 69ad4683-2ef6-47e8-a88f-d1153e (Blood Derived Normal), aliquot 69ad4683-2ef6-47e8-a88f-d1153e_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32b224cc-609c-4e01-8203-00d195335e48

The open-access MAF lists 1,011 somatic variants for this specimen: 684 protein-altering or splice-affecting, 192 silent, 135 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 471, Silent 192, Frame Shift Del 134, Intron 66, 3'UTR 26, Frame Shift Ins 25, Nonsense Mutation 24, RNA 16, Splice Site 16, 5'UTR 14, Splice Region 8, 5'Flank 7.

Variants (750 of 1,011; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTL6A | c.1129C>T p.R377W | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs868064163, COSV52023332; ClinVar: likely pathogenic; called by muse, mutect2
- ANKRD11 | c.6792del p.A2265Pfs*72 | Frame Shift Del (DEL) | VAF 40/178 reads (22%) | catalogued as rs878855327; ClinVar: pathogenic; called by pindel, varscan2
- CREBBP | c.3836+1G>A p.X1279_splice | Splice Site (SNP) | VAF 11/78 reads (14%) | catalogued as rs200782888, CS056749, COSV52117332; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2B | c.521del p.P174Qfs*20 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | catalogued as rs763183959; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MEN1 | c.1561del p.R521Gfs*43 | Frame Shift Del (DEL) | VAF 56/232 reads (24%) | catalogued as rs767319284, CD972318, CM080439, COSV53644931; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 47/167 reads (28%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PRPF8 | c.5804G>A p.R1935H | Missense Mutation (SNP) | VAF 69/253 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555550617, CM149178, COSV59268009; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RPGRIP1L | c.1329del p.K443Nfs*3 | Frame Shift Del (DEL) | VAF 52/267 reads (19%) | catalogued as rs749987648; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- STAG2 | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 21/99 reads (21%) | hotspot (GDC flag); catalogued as COSV54350685, COSV54365974; called by muse, mutect2, varscan2
- TRPV4 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 51/281 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.051); catalogued as rs397514494, CM126059; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.2422G>A p.G808R | Missense Mutation (SNP) | VAF 54/263 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as rs761223867; called by muse, mutect2, varscan2
- ABCA9 | c.3498del p.F1166Lfs*5 | Frame Shift Del (DEL) | VAF 19/139 reads (14%) | catalogued as rs1177267466; called by mutect2, pindel, varscan2
- ABHD11 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 86/451 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.106); catalogued as rs147198994, COSV56105232; called by muse, mutect2, varscan2
- ABLIM3 | c.1324C>T p.R442W | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs984646252; called by muse, varscan2
- AC004832.3 | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs369745248; called by muse, mutect2, varscan2
- AC099489.1 | c.4651C>T p.R1551* | Nonsense Mutation (SNP) | VAF 21/133 reads (16%) | catalogued as rs758217080; called by muse, mutect2, varscan2
- ACBD3 | c.766G>A p.V256M | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.034); catalogued as rs200702189, COSV64730971; called by muse, mutect2, varscan2
- ACTL6A | c.269del p.N90Mfs*47 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | catalogued as rs1560010257; called by mutect2, pindel
- ADAD2 | c.1082C>T p.P361L (on ENST00000315906 / NM_001145400.2; = p.P443L on NM_139174.4) | Missense Mutation (SNP) | VAF 46/206 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766729531, COSV51894364; called by muse, mutect2, varscan2
- ADCY7 | c.1750G>A p.E584K | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.378); catalogued as rs753451020; called by muse, mutect2, varscan2
- ADGRB1 | c.1311G>C p.R437S | Missense Mutation (SNP) | VAF 57/317 reads (18%) | SIFT tolerated (0.77); PolyPhen benign (0.127); catalogued as rs1408945154, COSV60101267; called by muse, mutect2, varscan2
- ADGRV1 | c.626del p.P209Lfs*6 | Frame Shift Del (DEL) | VAF 37/187 reads (20%) | catalogued as rs756977835, COSV101316537, COSV67977494; called by mutect2, pindel, varscan2
- AFG3L2 | c.1679C>T p.T560M | Missense Mutation (SNP) | VAF 89/362 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs763265106, COSV52316656; called by muse, mutect2, varscan2
- AKAP9 | c.7285G>A p.A2429T (on ENST00000359028; = p.A2405T on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/302 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs61746591; called by muse, mutect2, varscan2
- ALOX12B | c.1462C>T p.R488C | Missense Mutation (SNP) | VAF 26/608 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1221632429, COSV59875270; called by muse, mutect2
- AMH | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.147); catalogued as rs1421371734; called by muse, mutect2, varscan2
- ANK2 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 56/280 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.436); catalogued as rs901601971, COSV52148836, COSV52150935; called by muse, mutect2, varscan2
- ANKRD24 | c.901del p.A301Pfs*27 | Frame Shift Del (DEL) | VAF 22/90 reads (24%) | catalogued as rs760607781; called by mutect2, pindel, varscan2
- ANKRD33B | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs1369272963; called by muse, mutect2, varscan2
- ANKRD6 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 33/185 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs747899705, COSV100329845; called by muse, mutect2, varscan2
- APPL1 | c.460del p.R154Efs*6 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | catalogued as rs749401724; called by mutect2, varscan2
- AR | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 42/215 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); catalogued as COSV65955458; called by muse, mutect2, varscan2
- ARF1 | c.107A>T p.K36M | Missense Mutation (SNP) | VAF 33/229 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV55254756; called by muse, mutect2, varscan2
- ARHGAP12 | c.1141G>A p.G381R | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1324430051; called by muse, mutect2, varscan2
- ARHGAP5 | c.2676del p.F892Lfs*9 | Frame Shift Del (DEL) | VAF 34/210 reads (16%) | catalogued as rs781483073; called by mutect2, pindel, varscan2
- ARRDC5 | c.65A>G p.E22G (on ENST00000381781; = p.E8G on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/293 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.759); catalogued as rs748076276; called by muse, mutect2, varscan2
- ARSF | c.1266-1G>T p.X422_splice | Splice Site (SNP) | VAF 31/138 reads (22%) | catalogued as COSV63841164; called by muse, mutect2, varscan2
- ART1 | c.703_705del p.F235del | In Frame Del (DEL) | VAF 93/572 reads (16%) | catalogued as rs1427241858; called by pindel, varscan2
- ASH1L | c.5105G>A p.R1702Q | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); catalogued as COSV100853451; called by muse, mutect2, varscan2
- ATXN2L | c.1340C>T p.P447L | Missense Mutation (SNP) | VAF 73/248 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs776349538; called by muse, mutect2, varscan2
- B4GALNT1 | c.988A>G p.M330V | Missense Mutation (SNP) | VAF 79/316 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57541302; called by muse, mutect2, varscan2
- BAG6 | c.1169del p.P390Qfs*61 | Frame Shift Del (DEL) | VAF 22/88 reads (25%) | catalogued as rs745882580; called by mutect2, varscan2
- BCL10 | c.271dup p.T91Nfs*12 | Frame Shift Ins (INS) | VAF 15/106 reads (14%) | catalogued as rs1027681039; called by mutect2, pindel, varscan2
- BCL11B | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs775853703; called by muse, mutect2, varscan2
- BCL6 | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 73/456 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.124); catalogued as rs772973428, COSV51653431; called by muse, mutect2, varscan2
- BCL9 | c.1727C>T p.P576L | Missense Mutation (SNP) | VAF 14/426 reads (3%) | SIFT tolerated (0.92); PolyPhen possibly damaging (0.578); catalogued as rs781860269, COSV52342734; called by muse, mutect2
- BEGAIN | c.1558del p.D520Tfs*57 | Frame Shift Del (DEL) | VAF 21/86 reads (24%) | catalogued as rs749168305; called by mutect2, varscan2
- BICD2 | c.746C>T p.T249M | Missense Mutation (SNP) | VAF 31/594 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs148937530; called by muse, mutect2
- BIN1 | c.168G>A p.T56= | Splice Region (SNP) | VAF 46/189 reads (24%) | catalogued as rs528828320; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BPIFB4 | c.1199C>T p.A400V | Missense Mutation (SNP) | VAF 55/324 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.926); catalogued as COSV100971710; called by muse, mutect2, varscan2
- BTBD2 | c.1511C>T p.A504V | Missense Mutation (SNP) | VAF 47/200 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.156); catalogued as rs1266915483; called by muse, mutect2, varscan2
- C18orf25 | c.404C>T p.T135I | Missense Mutation (SNP) | VAF 92/377 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV99960293; called by muse, mutect2, varscan2
- CAMTA1 | c.3217G>A p.A1073T | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs752362812, COSV100352766; called by muse, mutect2, varscan2
- CASP7 | c.375del p.A126Lfs*17 | Frame Shift Del (DEL) | VAF 16/124 reads (13%) | catalogued as rs1247046723, COSV61881818; called by mutect2, pindel, varscan2
- CASZ1 | c.4342T>C p.C1448R | Missense Mutation (SNP) | VAF 40/714 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768450888; called by muse, mutect2
- CCDC157 | c.1655C>T p.T552I | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs138136556; called by muse, mutect2, varscan2
- CCDC168 | c.14888A>G p.E4963G | Missense Mutation (SNP) | VAF 55/359 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs778740973; called by muse, mutect2, varscan2
- CCDC168 | c.6356del p.N2119Tfs*6 | Frame Shift Del (DEL) | VAF 70/509 reads (14%) | catalogued as rs1349277202; called by mutect2, pindel, varscan2
- CCDC33 | c.103G>A p.V35M | Missense Mutation (SNP) | VAF 50/273 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs1280455830; called by muse, mutect2, varscan2
- CCDC74A | c.776del p.P259Qfs*2 | Frame Shift Del (DEL) | VAF 20/141 reads (14%) | catalogued as rs772061983; called by mutect2, varscan2
- CCNO | c.263A>G p.Q88R | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1561121754; called by muse, mutect2, varscan2
- CCZ1 | c.853G>A p.G285R | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs752066546; called by muse, mutect2, varscan2
- CDC42BPA | c.3818T>G p.L1273R (on ENST00000334218 / NM_001366019.2; = p.L1260R on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/163 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62013538; called by muse, mutect2
- CDHR5 | c.1178C>T p.S393L | Missense Mutation (SNP) | VAF 38/241 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs548971527, COSV57645564; called by muse, mutect2, varscan2
- CDKAL1 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51182167; called by muse, mutect2, varscan2
- CDKN2A | c.281T>A p.L94Q | Missense Mutation (SNP) | VAF 36/728 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM035015, CM097978, COSV58696521; called by muse, mutect2
- CEP164 | c.2741G>A p.R914Q | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs550799764, COSV54040365; called by muse, mutect2, varscan2
- CEP192 | c.4459A>G p.T1487A | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as rs1475215845; called by muse, varscan2
- CFAP206 | c.1430del p.N477Ifs*4 | Frame Shift Del (DEL) | VAF 30/119 reads (25%) | catalogued as rs751492244; called by mutect2, varscan2
- CFAP46 | c.4523C>T p.A1508V | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1033776974, COSV63951429; called by muse, mutect2, varscan2
- CHD8 | c.7112del p.N2371Ifs*6 (on ENST00000646647 / NM_001170629.2; = p.N2092Ifs*6 on NM_020920.4) | Frame Shift Del (DEL) | VAF 20/93 reads (22%) | catalogued as rs751094013; called by mutect2, varscan2
- CLEC16A | c.2950G>A p.V984I | Missense Mutation (SNP) | VAF 44/276 reads (16%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); catalogued as rs765434045, COSV55488382; called by muse, mutect2, varscan2
- COL14A1 | c.2537G>A p.R846H | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs901427317, COSV52849813, COSV52852703; called by muse, mutect2, varscan2
- COL1A1 | c.1675G>A p.A559T | Missense Mutation (SNP) | VAF 63/319 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.093); catalogued as rs558173513, COSV56803565; called by muse, mutect2, varscan2
- COL4A4 | c.3514G>A p.G1172R | Missense Mutation (SNP) | VAF 55/280 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1364773011, COSV104395237; called by muse, mutect2, varscan2
- CPAMD8 | c.454C>A p.R152S (on ENST00000651564; = p.R105S on NM_015692.5) | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.243); catalogued as rs531505285, COSV52233260; called by mutect2, varscan2
- CSMD3 | c.8765G>A p.S2922N (on ENST00000297405 / NM_001363185.1; = p.S2753N on NM_052900.3) | Missense Mutation (SNP) | VAF 43/313 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs746846872; called by muse, mutect2, varscan2
- CT47B1 | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 97/502 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.099); catalogued as rs1474988613; called by muse, mutect2, varscan2
- CTDP1 | c.1031T>C p.V344A | Missense Mutation (SNP) | VAF 24/446 reads (5%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs1305827228; called by muse, mutect2
- CTSB | c.992G>T p.R331L | Missense Mutation (SNP) | VAF 41/229 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV61540563; called by mutect2, varscan2
- CYB5R4 | c.741del p.E248Rfs*12 | Frame Shift Del (DEL) | VAF 20/158 reads (13%) | catalogued as rs745836350; called by mutect2, varscan2
- CYP1A1 | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 10/177 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as rs1171289597; called by muse, mutect2
- CYP2W1 | c.216del p.R73Afs*7 | Frame Shift Del (DEL) | VAF 28/123 reads (23%) | catalogued as COSV58269871; called by mutect2, pindel, varscan2
- CYP4Z1 | c.1387A>G p.K463E | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1362515073; called by muse, mutect2, varscan2
- DCST1 | c.1408C>G p.L470V | Missense Mutation (SNP) | VAF 28/218 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.355); catalogued as rs202162660, COSV55063674; called by mutect2, varscan2
- DGKB | c.1544A>C p.H515P | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs779596201; called by mutect2, varscan2
- DOCK7 | c.1419del p.F473Lfs*8 | Frame Shift Del (DEL) | VAF 11/49 reads (22%) | catalogued as rs1557822062, COSV51995102; called by mutect2, pindel, varscan2
- DPEP1 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 48/212 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1043397364, COSV55358954; called by muse, mutect2, varscan2
- EDRF1 | c.2698G>A p.A900T (on ENST00000356792 / NM_001202438.2; = p.A866T on NM_015608.2) | Missense Mutation (SNP) | VAF 58/688 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200332695; called by muse, mutect2
- EEF1AKNMT | c.692G>A p.R231H (on ENST00000361735 / NM_015935.5; = p.R145H on NM_014955.3) | Missense Mutation (SNP) | VAF 76/508 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs765441059, COSV62282463; called by muse, mutect2, varscan2
- EFHB | c.1151C>T p.T384M | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.123); catalogued as rs145670243; called by muse, varscan2
- EIF4G1 | c.2501C>T p.T834I (on ENST00000346169 / NM_198241.3; = p.T639I on NM_004953.5) | Missense Mutation (SNP) | VAF 91/431 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as rs747850664; called by muse, mutect2, varscan2
- ENAM | c.2223A>G p.I741M | Missense Mutation (SNP) | VAF 58/310 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as rs1440234835; called by muse, mutect2, varscan2
- ENOX1 | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 36/200 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs780160910; called by muse, mutect2, varscan2
- ESPNL | c.281del p.G94Afs*39 | Frame Shift Del (DEL) | VAF 14/56 reads (25%) | catalogued as rs770935577; called by mutect2, pindel
- EVI5 | c.1222del p.M408* | Frame Shift Del (DEL) | VAF 19/56 reads (34%) | catalogued as rs760182064; called by mutect2, varscan2
- EWSR1 | c.1677G>A p.P559= | Splice Region (SNP) | VAF 20/104 reads (19%) | catalogued as rs1370641709; called by muse, mutect2, varscan2
- F8 | c.3870dup p.G1291Rfs*29 | Frame Shift Ins (INS) | VAF 70/361 reads (19%) | catalogued as rs1426645898; called by mutect2, varscan2
- FAM189B | c.1187dup p.R397Tfs*12 | Frame Shift Ins (INS) | VAF 35/211 reads (17%) | catalogued as rs768391432; called by mutect2, pindel, varscan2
- FAM47A | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs753875155, COSV60498289, COSV60499246; called by muse, mutect2, varscan2
- FAT2 | c.1369del p.L457Sfs*24 | Frame Shift Del (DEL) | VAF 91/432 reads (21%) | catalogued as COSV55815079; called by mutect2, pindel, varscan2
- FLG | c.2176G>T p.G726W | Missense Mutation (SNP) | VAF 204/1182 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs139749779; called by mutect2, varscan2
- FLT3LG | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 54/194 reads (28%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs1266913005; called by mutect2, varscan2
- FREM2 | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 59/306 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs1201570968; called by muse, mutect2, varscan2
- FREM2 | c.8201G>A p.R2734H | Missense Mutation (SNP) | VAF 49/251 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); catalogued as rs778134271, COSV54828481; called by muse, mutect2, varscan2
- FRYL | c.5968G>A p.V1990M | Missense Mutation (SNP) | VAF 22/366 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.294); catalogued as rs765103418; called by muse, mutect2
- FUBP1 | c.778G>A p.G260S | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs367853057; called by muse, mutect2, varscan2
- GABRB1 | c.1399G>A p.V467I | Missense Mutation (SNP) | VAF 53/218 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.023); catalogued as COSV54974186, COSV99040356, COSV99781801; called by muse, mutect2, varscan2
- GALR3 | c.293T>C p.V98A | Missense Mutation (SNP) | VAF 46/198 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1292229943; called by muse, mutect2, varscan2
- GBA2 | c.2587C>A p.P863T | Missense Mutation (SNP) | VAF 107/406 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100147983; called by mutect2, varscan2
- GBP5 | c.692del p.K231Rfs*26 | Frame Shift Del (DEL) | VAF 20/140 reads (14%) | catalogued as rs767245260; called by mutect2, pindel, varscan2
- GGT5 | c.866del p.G289Vfs*11 | Frame Shift Del (DEL) | VAF 19/113 reads (17%) | catalogued as COSV54073059; called by mutect2, pindel, varscan2
- GIGYF1 | c.331dup p.L111Pfs*20 | Frame Shift Ins (INS) | VAF 54/268 reads (20%) | catalogued as rs763147690; called by mutect2, varscan2
- GIPC3 | c.868C>T p.R290C (on ENST00000644946; = p.S285= on NM_133261.3) | Missense Mutation (SNP) | VAF 82/335 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as rs766192644, COSV59260175; called by muse, mutect2, varscan2
- GJA3 | c.799G>A p.G267R | Missense Mutation (SNP) | VAF 16/316 reads (5%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.921); catalogued as rs1303288023; called by muse, mutect2
- GJA8 | c.503G>A p.G168D | Missense Mutation (SNP) | VAF 31/1004 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99569699; called by muse, mutect2
- GKAP1 | c.166dup p.R56Kfs*14 | Frame Shift Ins (INS) | VAF 46/228 reads (20%) | catalogued as rs747729701; called by mutect2, varscan2
- GLYR1 | c.406G>A p.V136M | Missense Mutation (SNP) | VAF 53/218 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.144); catalogued as rs953397386, COSV58926927; called by muse, mutect2, varscan2
- GMPPB | c.787G>A p.G263S | Missense Mutation (SNP) | VAF 61/270 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.49); catalogued as rs753366203; ClinVar: uncertain significance; called by muse, varscan2
- GPANK1 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1261272958, COSV100788966; called by muse, mutect2, varscan2
- GPR143 | c.40C>T p.R14W | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as COSV66633299; called by muse, mutect2, varscan2
- GPX4 | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 57/176 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as rs375048133; called by muse, mutect2, varscan2
- GRAMD1B | c.1471C>T p.R491W | Missense Mutation (SNP) | VAF 53/213 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs1390495624, COSV100454305; called by muse, mutect2, varscan2
- HAX1 | c.463del p.Q155Nfs*59 | Frame Shift Del (DEL) | VAF 48/385 reads (12%) | catalogued as COSV55172930; called by mutect2, pindel, varscan2
- HDHD3 | c.415C>T p.R139* | Nonsense Mutation (SNP) | VAF 114/519 reads (22%) | catalogued as rs200575167; called by muse, mutect2, varscan2
- HRH3 | c.1147G>A p.A383T | Missense Mutation (SNP) | VAF 88/411 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs146277958; called by muse, mutect2, varscan2
- HS3ST5 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 65/574 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.414); catalogued as rs757564478; called by muse, mutect2, varscan2
- HSPA1A | c.119G>A p.S40N | Missense Mutation (SNP) | VAF 101/361 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.9); catalogued as rs779938408; called by muse, mutect2, varscan2
- IFT140 | c.1322G>A p.R441H | Missense Mutation (SNP) | VAF 46/210 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs776567773, COSV68505674; called by muse, mutect2, varscan2
- IGF2R | c.3949del p.D1317Tfs*27 | Frame Shift Del (DEL) | VAF 32/174 reads (18%) | catalogued as rs760021495; called by mutect2, varscan2
- IGSF9 | c.1027C>T p.R343C (on ENST00000368094 / NM_001135050.2; = p.R327C on NM_020789.4) | Missense Mutation (SNP) | VAF 36/256 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as rs368333835; called by muse, mutect2, varscan2
- IKBKE | c.763G>A p.G255R | Missense Mutation (SNP) | VAF 30/204 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1553385836, COSV65625277; called by muse, mutect2, varscan2
- IL12RB1 | c.1618G>A p.E540K | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs754721392; called by muse, mutect2, varscan2
- IL5 | c.382A>G p.T128A | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.485); catalogued as rs1306705190; called by muse, mutect2, varscan2
- IRF8 | c.245T>C p.L82S | Missense Mutation (SNP) | VAF 53/256 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1333675827; called by muse, mutect2, varscan2
- IRX4 | c.23A>G p.Y8C | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51473796; called by muse, mutect2
- ITPKA | c.1259C>T p.T420I | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53028130; called by muse, mutect2, varscan2
- ITPR2 | c.3020C>T p.A1007V | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs535598972, COSV67277748; called by muse, mutect2, varscan2
- JADE1 | c.2348G>A p.R783Q | Missense Mutation (SNP) | VAF 54/318 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs778587937; called by muse, mutect2, varscan2
- JMJD6 | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs541473621, COSV57971327; called by muse, mutect2
- KCTD3 | c.1282A>G p.M428V | Missense Mutation (SNP) | VAF 32/233 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.05); catalogued as rs773215363; called by muse, mutect2, varscan2
- KIAA1755 | c.3492del p.R1165Gfs*38 | Frame Shift Del (DEL) | VAF 51/212 reads (24%) | catalogued as rs772495335; called by mutect2, pindel, varscan2
- KIF13B | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV104440110; called by muse, mutect2, varscan2
- KIF17 | c.602C>T p.T201M | Missense Mutation (SNP) | VAF 156/749 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775858871; called by muse, mutect2, varscan2
- KNOP1 | c.467del p.K156Rfs*57 | Frame Shift Del (DEL) | VAF 60/274 reads (22%) | catalogued as rs960845807, COSV54929560; called by mutect2, varscan2
- LEFTY1 | c.454G>A p.V152I | Missense Mutation (SNP) | VAF 64/413 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs1410615103; called by muse, mutect2, varscan2
- LENG8 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 43/197 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs775076605, COSV58727487; called by muse, mutect2
- LMX1B | c.228G>A p.W76* | Nonsense Mutation (SNP) | VAF 12/242 reads (5%) | catalogued as CM992907; called by muse, mutect2
- LRP1B | c.5611C>T p.R1871C | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs779772138; called by muse, mutect2, varscan2
- LRRTM1 | c.1076C>T p.A359V | Missense Mutation (SNP) | VAF 99/468 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.154); catalogued as COSV54437858; called by muse, mutect2, varscan2
- LRWD1 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs749456596; called by muse, mutect2, varscan2
- LYG1 | c.439A>G p.T147A | Missense Mutation (SNP) | VAF 14/151 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs754478037; called by muse, mutect2
- MADD | c.4547G>T p.R1516L | Missense Mutation (SNP) | VAF 61/213 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100212180; called by muse, mutect2, varscan2
- MAGEE2 | c.133del p.Q45Sfs*27 | Frame Shift Del (DEL) | VAF 25/99 reads (25%) | catalogued as rs1159257962; called by mutect2, pindel, varscan2
- MAGEL2 | c.2910G>A p.W970* | Nonsense Mutation (SNP) | VAF 46/281 reads (16%) | catalogued as COSV58568493; called by muse, mutect2, varscan2
- MBD6 | c.2200del p.Q734Nfs*18 | Frame Shift Del (DEL) | VAF 12/62 reads (19%) | catalogued as rs749738168; called by mutect2, varscan2
- MCF2L2 | c.70C>T p.H24Y | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.36); catalogued as rs780031628; called by muse, mutect2, varscan2
- MCMDC2 | c.866G>A p.C289Y | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs575574051; called by muse, mutect2, varscan2
- MDN1 | c.12718C>T p.R4240W | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1245194735, COSV65528211; called by muse, mutect2, varscan2
- MEGF6 | c.4318dup p.A1440Gfs*4 | Frame Shift Ins (INS) | VAF 32/216 reads (15%) | catalogued as rs759225724; called by mutect2, varscan2
- MEGF8 | c.497del p.G166Vfs*53 | Frame Shift Del (DEL) | VAF 59/264 reads (22%) | catalogued as rs762115034; called by mutect2, pindel, varscan2
- MEN1 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.67); catalogued as rs1440986026; called by muse, mutect2, varscan2
- MEX3B | c.1037del p.G346Efs*181 | Frame Shift Del (DEL) | VAF 34/147 reads (23%) | catalogued as rs1406688622; called by mutect2, pindel, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 9/25 reads (36%) | catalogued as rs762448666; called by mutect2, pindel, varscan2
- MLXIP | c.544G>A p.V182M | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs762555531, COSV59838817; called by muse, mutect2, varscan2
- MMP12 | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 29/164 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.611); catalogued as rs183458117, COSV58260645, COSV58261545; called by muse, mutect2, varscan2
- MMRN2 | c.1687C>T p.R563W | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.055); catalogued as rs1406260169, COSV104426706; called by muse, mutect2
- MRPL16 | c.367C>T p.R123* | Nonsense Mutation (SNP) | VAF 87/417 reads (21%) | catalogued as rs1414064269, COSV55696680; called by muse, mutect2, varscan2
- MRPL38 | c.644C>T p.T215M | Missense Mutation (SNP) | VAF 64/283 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201114030, COSV53934995; called by muse, mutect2, varscan2
- MUC16 | c.39709G>A p.A13237T | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.921); catalogued as rs759702185, COSV66691400; called by muse, mutect2, varscan2
- MX1 | c.1087G>A p.D363N | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.961); catalogued as rs139733063; called by muse, mutect2, varscan2
- MYBPH | c.1384del p.E462Rfs*114 | Frame Shift Del (DEL) | VAF 25/181 reads (14%) | catalogued as COSV55141095; called by mutect2, pindel, varscan2
- MYC | c.605G>A p.S202N (on ENST00000377970; = p.S217N on NM_002467.6) | Missense Mutation (SNP) | VAF 9/168 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.112); catalogued as rs922203242, COSV52371984; called by muse, mutect2
- MYH14 | c.3818G>A p.R1273H | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); catalogued as rs375213477, COSV51824798; called by muse, mutect2, varscan2
- MYO15A | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 132/560 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.931); catalogued as rs923156097, COSV99234444; called by muse, mutect2, varscan2
- MYO18B | c.107del p.G36Afs*23 | Frame Shift Del (DEL) | VAF 24/118 reads (20%) | catalogued as COSV59140741, COSV59152715; called by mutect2, pindel, varscan2
- MYPOP | c.1139dup p.H381Tfs*69 | Frame Shift Ins (INS) | VAF 11/56 reads (20%) | catalogued as rs757587344; called by mutect2, varscan2
- N4BP2 | c.4949del p.N1650Mfs*17 | Frame Shift Del (DEL) | VAF 8/58 reads (14%) | catalogued as rs763929397; called by mutect2, varscan2
- NARS1 | c.107T>C p.V36A | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1282484273; called by muse, mutect2
- NBPF10 | c.11064A>T p.K3688N | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.888); catalogued as rs782282279; called by muse, varscan2
- NCAM2 | c.1414C>T p.R472C | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs767687292, COSV53092867; called by muse, mutect2, varscan2
- NME5 | c.200T>C p.F67S | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1293624719; called by muse, mutect2
- NOTCH1 | c.4754T>C p.L1585P | Missense Mutation (SNP) | VAF 80/360 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53025649, COSV53029975, COSV53033143; called by muse, mutect2, varscan2
- NOTCH1 | c.4136del p.T1379Rfs*66 | Frame Shift Del (DEL) | VAF 21/131 reads (16%) | catalogued as COSV53031966, COSV53064515; called by mutect2, pindel, varscan2
- NPY4R | c.638T>C p.I213T | Missense Mutation (SNP) | VAF 51/164 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.081); catalogued as rs1554989311; called by muse, mutect2, varscan2
- NT5DC4 | c.767C>T p.T256M | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.401); catalogued as rs904701383; called by muse, mutect2
- OPHN1 | c.1226G>A p.R409H | Missense Mutation (SNP) | VAF 85/368 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs771624663, COSV62787259; called by muse, mutect2, varscan2
- OR10C1 | c.661C>T p.R221C (on ENST00000622521; = p.R219C on NM_013941.3) | Missense Mutation (SNP) | VAF 264/777 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV65822599; called by muse, mutect2, varscan2
- OR2C3 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 121/554 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.404); catalogued as COSV63576195; called by muse, mutect2, varscan2
- OR4K13 | c.901del p.R301Dfs*71 | Frame Shift Del (DEL) | VAF 11/60 reads (18%) | catalogued as rs749899868, COSV100237879; called by mutect2, pindel, varscan2
- OTUD6A | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 72/336 reads (21%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.862); catalogued as rs370977424, COSV57972519; called by muse, mutect2, varscan2
- OTX1 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 167/670 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs375731189, COSV56995825; called by muse, mutect2, varscan2
- PAH | c.620A>G p.N207S | Missense Mutation (SNP) | VAF 129/595 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.683); catalogued as rs62508721, CM971129, COSV61013938; ClinVar: conflicting interpretations of pathogenicity / not provided; called by muse, mutect2, varscan2
- PALD1 | c.539A>G p.Y180C | Missense Mutation (SNP) | VAF 45/247 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772627616; called by muse, mutect2, varscan2
- PAQR9 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 51/280 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs760365185, COSV61418151; called by muse, mutect2, varscan2
- PAX6 | c.1124dup p.H376Tfs*36 | Frame Shift Ins (INS) | VAF 78/406 reads (19%) | catalogued as rs756801119; called by mutect2, varscan2
- PCDH17 | c.1739C>T p.A580V | Missense Mutation (SNP) | VAF 102/626 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.097); catalogued as COSV64976694; called by muse, mutect2, varscan2
- PCDH19 | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 118/453 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV55257022; called by muse, mutect2, varscan2
- PCDHGB6 | c.1525G>A p.A509T | Missense Mutation (SNP) | VAF 131/523 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.605); catalogued as rs1000014772, COSV53909164; called by muse, mutect2, varscan2
- PCDHGB7 | c.988C>T p.R330W | Missense Mutation (SNP) | VAF 80/375 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.738); catalogued as rs1266068276; called by mutect2, varscan2
- PCDHGC3 | c.2066del p.N689Ifs*10 | Frame Shift Del (DEL) | VAF 82/331 reads (25%) | catalogued as rs1156842877; called by mutect2, varscan2
- PDP2 | c.299G>A p.S100N | Missense Mutation (SNP) | VAF 98/495 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs1322622971; called by muse, mutect2, varscan2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 22/87 reads (25%) | catalogued as rs769717544; called by mutect2, varscan2
- PIGN | c.2577-5del | Splice Region (DEL) | VAF 10/48 reads (21%) | catalogued as rs138671843; ClinVar: benign / likely benign; called by mutect2, varscan2
- PKD1 | c.11902C>T p.R3968C (on ENST00000262304 / NM_001009944.3; = p.R3967C on NM_000296.4) | Missense Mutation (SNP) | VAF 96/347 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs781636453; called by muse, mutect2, varscan2
- PKNOX2 | c.27del p.A10Lfs*2 | Frame Shift Del (DEL) | VAF 51/202 reads (25%) | catalogued as COSV53545219; called by mutect2, pindel, varscan2
- PLEC | c.12145C>T p.R4049W (on ENST00000322810 / NM_201380.4; = p.R3939W on NM_000445.5) | Missense Mutation (SNP) | VAF 128/689 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.153); catalogued as rs782136681, COSV99055271; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLIN5 | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.743); catalogued as rs377144070, COSV67850922; called by muse, mutect2, varscan2
- POLN | c.1373G>T p.G458V | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV101242643; called by mutect2, varscan2
- PPM1J | c.1427G>A p.R476H | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.483); catalogued as rs201204322; called by muse, mutect2
- PPM1K | c.1108C>T p.R370* | Nonsense Mutation (SNP) | VAF 9/100 reads (9%) | catalogued as COSV55797586, COSV55797828; called by muse, mutect2
- PPP4R3C | c.1010dup p.K338Qfs*20 | Frame Shift Ins (INS) | VAF 48/196 reads (24%) | catalogued as rs774823546; called by mutect2, varscan2
- PPP6R1 | c.157del p.H53Tfs*33 | Frame Shift Del (DEL) | VAF 34/187 reads (18%) | catalogued as COSV69800555; called by mutect2, pindel, varscan2
- PRAMEF11 | c.542A>G p.H181R | Missense Mutation (SNP) | VAF 130/658 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV101463160; called by muse, mutect2, varscan2
- PRAMEF2 | c.496T>C p.Y166H | Missense Mutation (SNP) | VAF 41/193 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.248); catalogued as rs769780145; called by muse, mutect2, varscan2
- PRMT7 | c.1133G>A p.R378Q | Missense Mutation (SNP) | VAF 47/219 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs757058334, COSV59835485; called by muse, mutect2, varscan2
- PTPDC1 | c.1022G>A p.S341N (on ENST00000375360 / NM_177995.3; = p.S393N on NM_152422.4) | Missense Mutation (SNP) | VAF 92/353 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as rs1032095905; called by muse, mutect2, varscan2
- PTPN14 | c.1330G>A p.D444N | Missense Mutation (SNP) | VAF 60/628 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV65288925; called by muse, mutect2
- PTPN14 | c.316G>A p.V106M | Missense Mutation (SNP) | VAF 27/192 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778125245; called by muse, mutect2, varscan2
- PTPRK | c.826C>T p.R276* | Nonsense Mutation (SNP) | VAF 11/72 reads (15%) | catalogued as rs771852470; called by muse, mutect2, varscan2
- RAPGEF6 | c.1918del p.S640Vfs*59 | Frame Shift Del (DEL) | VAF 24/162 reads (15%) | catalogued as rs752725730; called by mutect2, varscan2
- RASA3 | c.1463C>T p.A488V | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs986093149, COSV61866365, COSV61872104; called by muse, mutect2, varscan2
- RBP3 | c.1516C>A p.L506I | Missense Mutation (SNP) | VAF 121/566 reads (21%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.922); catalogued as rs782498728; called by muse, mutect2, varscan2
- RELN | c.2408A>G p.N803S | Missense Mutation (SNP) | VAF 28/179 reads (16%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.952); catalogued as rs1310555467; called by muse, mutect2, varscan2
- RGPD4 | c.5035A>G p.T1679A | Missense Mutation (SNP) | VAF 46/202 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.855); catalogued as COSV61749641; called by muse, mutect2, varscan2
- RIMS1 | c.54del p.M19Cfs*7 | Frame Shift Del (DEL) | VAF 20/147 reads (14%) | catalogued as rs1378143186; called by mutect2, pindel, varscan2
- RNF123 | c.1629+1del | Frame Shift Del (DEL) | VAF 66/282 reads (23%) | catalogued as COSV59688684; called by mutect2, varscan2
- RNF146 | c.804_806del p.E268del (on ENST00000368314 / NM_001242850.2; = p.E267del on NM_030963.3 and 2 other RefSeq transcripts) | In Frame Del (DEL) | VAF 76/556 reads (14%) | catalogued as rs760706934; called by pindel, varscan2
- RNF214 | c.1268G>T p.R423M | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100326404; called by muse, varscan2
- RNF31 | c.2129G>A p.R710Q | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.644); catalogued as rs756736553; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 15/89 reads (17%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RTEL1 | c.2351_2353del p.F784del | In Frame Del (DEL) | VAF 22/124 reads (18%) | catalogued as rs771771098; called by pindel, varscan2
- RTL9 | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 100/546 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.103); catalogued as rs1569433493, COSV71825516, COSV71825588; called by muse, mutect2, varscan2
- SBNO2 | c.1378G>A p.V460I | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); catalogued as rs756978453; called by muse, varscan2
- SCAF8 | c.1937C>T p.A646V | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.709); catalogued as rs148306012; called by muse, mutect2, varscan2
- SEC23IP | c.1025G>A p.R342H | Missense Mutation (SNP) | VAF 59/266 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1217186669, COSV64832704; called by muse, mutect2, varscan2
- SEMA5A | c.2854G>A p.V952M | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.635); catalogued as rs1221228484, COSV101228206; called by muse, mutect2, varscan2
- SEMA6C | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771054527; called by muse, mutect2, varscan2
- SHISA7 | c.548del p.G183Afs*48 | Frame Shift Del (DEL) | VAF 6/23 reads (26%) | catalogued as rs1341354513; called by mutect2, pindel, varscan2
- SHPRH | c.1700A>G p.Y567C | Missense Mutation (SNP) | VAF 112/624 reads (18%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs374271207; called by muse, mutect2, varscan2
- SIK2 | c.736C>T p.H246Y | Missense Mutation (SNP) | VAF 42/206 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.884); catalogued as rs1238557118; called by muse, mutect2, varscan2
- SLC16A1 | c.325G>A p.V109I | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.29); catalogued as rs754077369; called by muse, mutect2, varscan2
- SLC16A7 | c.786del p.F262Lfs*39 | Frame Shift Del (DEL) | VAF 52/333 reads (16%) | catalogued as COSV53899988; called by mutect2, pindel, varscan2
- SLC25A48 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 104/316 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV50848046; called by muse, varscan2
- SLC30A2 | c.143A>G p.Q48R | Missense Mutation (SNP) | VAF 54/285 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.028); catalogued as COSV65332956; called by muse, mutect2, varscan2
- SMTN | c.1605dup p.S536Qfs*2 | Frame Shift Ins (INS) | VAF 22/103 reads (21%) | catalogued as rs758895137; called by mutect2, varscan2
- SNX2 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.731); catalogued as COSV101075540; called by muse, mutect2, varscan2
- SP140 | c.2146T>G p.C716G | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59452548; called by muse, mutect2, varscan2
- SPTA1 | c.3916A>G p.S1306G | Missense Mutation (SNP) | VAF 66/464 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs1332320998; called by muse, mutect2, varscan2
- SPTB | c.5737C>T p.R1913C | Missense Mutation (SNP) | VAF 32/696 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs752611530; called by muse, mutect2
- STAMBPL1 | c.1214del p.K405Rfs*21 | Frame Shift Del (DEL) | VAF 31/182 reads (17%) | catalogued as rs752994755; called by mutect2, varscan2
- STOM | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766711234; called by muse, mutect2, varscan2
- SUDS3 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100820006, COSV64349091; called by muse, mutect2, varscan2
- SUMF1 | c.533C>A p.P178H | Missense Mutation (SNP) | VAF 52/237 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs113185435, COSV99794848; called by muse, mutect2, varscan2
- SVOP | c.1396G>A p.G466S | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.833); catalogued as rs373382687; called by muse, mutect2, varscan2
- SYK | c.1265A>G p.N422S | Missense Mutation (SNP) | VAF 75/417 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.391); catalogued as COSV101002637; called by muse, mutect2, varscan2
- TACC2 | c.8054C>T p.A2685V (on ENST00000334433; = p.A763V on NM_006997.4) | Missense Mutation (SNP) | VAF 46/185 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs865827548; called by muse, mutect2, varscan2
- TAF9 | c.472A>G p.S158G | Missense Mutation (SNP) | VAF 16/430 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.025); catalogued as rs1164562731; called by muse, mutect2
- TANGO6 | c.418T>C p.S140P | Missense Mutation (SNP) | VAF 69/260 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as rs1254094570; called by muse, mutect2, varscan2
- TAS2R42 | c.745del p.S249Pfs*18 | Frame Shift Del (DEL) | VAF 24/118 reads (20%) | catalogued as rs753101364; called by mutect2, varscan2
- TCF7L2 | c.1454del p.K485Sfs*23 (on ENST00000355995 / NM_001367943.1; = p.K462Sfs*23 on NM_030756.5) | Frame Shift Del (DEL) | VAF 38/158 reads (24%) | catalogued as rs745872748; called by mutect2, varscan2
- TCIRG1 | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 78/349 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as rs749921928, COSV55836628; called by muse, mutect2, varscan2
- TDRD6 | c.4558del p.M1520* | Frame Shift Del (DEL) | VAF 42/257 reads (16%) | catalogued as rs145334816, COSV60176047; called by mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 32/122 reads (26%) | catalogued as rs763321097; called by mutect2, varscan2
- TET3 | c.5378G>A p.R1793H | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as rs1416473503; called by muse, mutect2, varscan2
- TEX14 | c.1735A>G p.T579A (on ENST00000240361 / NM_001201457.2; = p.T573A on NM_031272.5) | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0.162); catalogued as rs774756253; called by muse, mutect2, varscan2
- TFCP2 | c.260C>T p.T87M | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99227656; called by muse, mutect2, varscan2
- THBS3 | c.42_44del p.L15del | In Frame Del (DEL) | VAF 30/139 reads (22%) | catalogued as rs765872931; called by pindel, varscan2
- TLE1 | c.1741G>A p.A581T | Missense Mutation (SNP) | VAF 49/262 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs980854823, COSV64722314; called by muse, mutect2, varscan2
- TMC2 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 75/232 reads (32%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs1035668319, COSV62649544; called by muse, mutect2, varscan2
- TMEM132E | c.1105C>T p.R369W (on ENST00000321639; = p.R459W on NM_001304438.2) | Missense Mutation (SNP) | VAF 10/155 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1456985738, COSV58695520; called by muse, mutect2
- TMEM39B | c.427G>A p.V143M | Missense Mutation (SNP) | VAF 55/254 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs149666383; called by muse, mutect2, varscan2
- TNRC18 | c.1895G>A p.R632Q | Missense Mutation (SNP) | VAF 71/400 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.194); catalogued as rs1158646112; called by muse, mutect2, varscan2
- TNRC6B | c.5174G>A p.R1725H (on ENST00000454349 / NM_001162501.2; = p.R1615H on NM_015088.3) | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs758298650, COSV57300336, COSV57307990; called by muse, mutect2, varscan2
- TOPAZ1 | c.1893del p.A632Lfs*5 | Frame Shift Del (DEL) | VAF 16/100 reads (16%) | catalogued as rs753884819, COSV59073348; called by mutect2, varscan2
- TRIM55 | c.1013G>A p.G338D | Missense Mutation (SNP) | VAF 52/336 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs146795651; called by mutect2, varscan2
- TRIO | c.8252C>T p.T2751M | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.698); catalogued as rs746758470, COSV100702653; called by muse, mutect2, varscan2
- TRIOBP | c.5867C>A p.P1956Q (on ENST00000644935 / NM_001039141.3; = p.P243Q on NM_007032.5) | Missense Mutation (SNP) | VAF 60/261 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as COSV58526222; called by muse, mutect2, varscan2
- TSBP1 | c.1629+2C>T | Missense Mutation (SNP) | VAF 52/124 reads (42%) | catalogued as rs941718641, COSV66657748; called by muse, mutect2, varscan2
- TTC23 | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs760600439, COSV50440936; called by muse, mutect2, varscan2
- TTC7A | c.487C>T p.R163W | Missense Mutation (SNP) | VAF 56/259 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs767380906, COSV55411678; called by muse, mutect2, varscan2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 28/121 reads (23%) | catalogued as rs763254614; called by mutect2, varscan2
- TTN | c.55223G>A p.R18408H (on ENST00000591111; = p.R10984H on NM_003319.4) | Missense Mutation (SNP) | VAF 35/156 reads (22%) | PolyPhen probably damaging (0.998); catalogued as rs200455644; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TXNRD3 | c.1108C>T p.R370C | Missense Mutation (SNP) | VAF 49/245 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs534871662; called by muse, mutect2, varscan2
- UBA1 | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 36/873 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60110939; called by muse, mutect2
- UBA52 | c.48G>T p.E16D | Missense Mutation (SNP) | VAF 32/196 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV55889576, COSV99723599; called by mutect2, varscan2
- UBR5 | c.6360del p.E2121Kfs*28 | Frame Shift Del (DEL) | VAF 18/121 reads (15%) | catalogued as rs763652408; called by mutect2, varscan2
- UBTF | c.167A>G p.E56G | Missense Mutation (SNP) | VAF 52/205 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV57184975; called by muse, mutect2, varscan2
- UCHL3 | c.94G>A p.V32I | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.081); catalogued as rs746951082; called by muse, mutect2, varscan2
- UCN2 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.048); catalogued as rs370633415, COSV56476395; called by muse, mutect2, varscan2
- UFL1 | c.682G>A p.G228R | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); catalogued as rs183052013; called by muse, varscan2
- UFL1 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as rs757348368, COSV65150409; called by muse, varscan2
- UNC93A | c.1264A>G p.M422V | Missense Mutation (SNP) | VAF 45/280 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.023); catalogued as rs753723378; called by muse, mutect2, varscan2
- USP9X | c.6566-2A>T p.X2189_splice | Splice Site (SNP) | VAF 17/52 reads (33%) | catalogued as rs1295737661; called by muse, mutect2, varscan2
- VPS13C | c.4429del p.I1477Lfs*24 (on ENST00000644861 / NM_020821.3; = p.I1434Lfs*24 on NM_017684.5) | Frame Shift Del (DEL) | VAF 26/90 reads (29%) | catalogued as rs756149444; called by mutect2, varscan2
- WASHC1 | c.776A>G p.D259G | Missense Mutation (SNP) | VAF 25/669 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1432737702; called by muse, mutect2
- WDR81 | c.1291G>A p.G431S | Missense Mutation (SNP) | VAF 65/252 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs781397816; called by muse, mutect2, varscan2
- WDR82 | c.317A>G p.H106R | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1310852478, COSV99627237; called by muse, mutect2, varscan2
- WNK3 | c.1156A>G p.I386V | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV63613112; called by muse, mutect2, varscan2
- WNT11 | c.206T>C p.V69A | Missense Mutation (SNP) | VAF 105/472 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV59444626; called by muse, mutect2, varscan2
- WNT16 | c.500dup p.C168Lfs*4 (on ENST00000222462 / NM_057168.2; = p.C158Lfs*4 on NM_016087.2) | Frame Shift Ins (INS) | VAF 34/289 reads (12%) | catalogued as rs771899177; called by mutect2, varscan2
- XIRP1 | c.4480C>A p.L1494M | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1352125171; called by muse, mutect2, varscan2
- ZBTB21 | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 80/382 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV60404279; called by muse, mutect2, varscan2
- ZDHHC17 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs766812634, COSV58352762; called by muse, mutect2, varscan2
- ZDHHC18 | c.559C>T p.Q187* | Nonsense Mutation (SNP) | VAF 29/196 reads (15%) | catalogued as rs750426748; called by muse, mutect2, varscan2
- ZFHX4 | c.940A>G p.S314G | Missense Mutation (SNP) | VAF 73/537 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99254355; called by muse, mutect2, varscan2
- ZFHX4 | c.8689G>A p.D2897N | Missense Mutation (SNP) | VAF 51/283 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1227968613, COSV51500031; called by muse, mutect2, varscan2
- ZNF132 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 74/310 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs759276688, COSV54234103; called by muse, mutect2, varscan2
- ZNF185 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 89/394 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as rs370621060; called by muse, mutect2, varscan2
- ZNF214 | c.1174G>A p.G392S | Missense Mutation (SNP) | VAF 108/426 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as rs1217317821, COSV53483647; called by muse, varscan2
- ZNF446 | c.1156del p.R386Dfs*228 | Frame Shift Del (DEL) | VAF 101/492 reads (21%) | catalogued as rs767518404, COSV100236296; called by mutect2, pindel, varscan2
- ZNF48 | c.745del p.R249Dfs*43 | Frame Shift Del (DEL) | VAF 24/113 reads (21%) | catalogued as rs780189754; called by mutect2, pindel, varscan2
- ZNF496 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs765186900, COSV54176633; called by muse, mutect2, varscan2
- ZNF540 | c.445del p.M149Cfs*12 | Frame Shift Del (DEL) | VAF 17/92 reads (18%) | catalogued as COSV100329754, COSV57108094; called by mutect2, pindel, varscan2
- ZNF581 | c.85C>A p.R29S | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs778892852, COSV54401821; called by muse, mutect2, varscan2
- ZNF79 | c.1039G>T p.A347S | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0.225); catalogued as COSV61070458; called by mutect2, varscan2
- ZNF813 | c.743G>A p.C248Y | Missense Mutation (SNP) | VAF 47/210 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); catalogued as rs752347034; called by muse, mutect2, varscan2
- ZNRF3 | c.1550C>T p.P517L (on ENST00000544604 / NM_001206998.2; = p.P417L on NM_032173.3) | Missense Mutation (SNP) | VAF 66/269 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs1162608502, COSV60436881; called by muse, varscan2
- ZNRF4 | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 89/409 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs749579210; called by muse, mutect2, varscan2
- ZXDA | c.583del p.A195Pfs*10 | Frame Shift Del (DEL) | VAF 56/190 reads (29%) | catalogued as COSV100699501; called by mutect2, varscan2
- ABCB10 | c.777G>T p.E259D | Missense Mutation (SNP) | VAF 80/620 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.105); called by mutect2, varscan2
- ABCB11 | c.163T>C p.S55P | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ABCC1 | c.1424T>G p.L475R | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- AC092143.1 | c.1300C>T p.P434S | Missense Mutation (SNP) | VAF 118/489 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ACTN2 | c.1633G>T p.V545F | Missense Mutation (SNP) | VAF 42/302 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- ACVR2A | c.1175T>C p.L392S | Missense Mutation (SNP) | VAF 10/205 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADAM15 | c.589del p.L197Wfs*13 | Frame Shift Del (DEL) | VAF 21/127 reads (17%) | called by mutect2, pindel, varscan2
- ADAM8 | c.1885T>C p.C629R | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS15 | c.979T>A p.C327S | Missense Mutation (SNP) | VAF 45/217 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADAMTSL1 | c.4339A>G p.I1447V | Missense Mutation (SNP) | VAF 22/496 reads (4%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2
- ADGRA3 | c.2112G>A p.W704* | Nonsense Mutation (SNP) | VAF 30/387 reads (8%) | called by muse, mutect2
- ADGRD2 | c.2834_2836del p.K946del | In Frame Del (DEL) | VAF 11/48 reads (23%) | called by pindel, varscan2
- ADGRV1 | c.2078A>G p.K693R | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- ADPRH | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 73/355 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- ADRA2B | c.86G>A p.G29D | Missense Mutation (SNP) | VAF 123/598 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- AGRN | c.5971C>A p.L1991M | Missense Mutation (SNP) | VAF 102/421 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AKAP13 | c.1725G>T p.E575D | Missense Mutation (SNP) | VAF 67/330 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AKAP17A | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 34/192 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- AKAP9 | c.6460dup p.T2154Nfs*6 (on ENST00000359028; = p.T2122Nfs*6 on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 37/155 reads (24%) | called by mutect2, pindel, varscan2
- AKR1C3 | c.547A>G p.K183E | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- AL117348.2 | c.868C>T p.R290* | Nonsense Mutation (SNP) | VAF 102/594 reads (17%) | called by muse, mutect2, varscan2
- ALKBH8 | c.373T>C p.W125R | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- AMOTL1 | c.1060C>T p.P354S | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ANKRD50 | c.389T>C p.L130P | Missense Mutation (SNP) | VAF 122/604 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- AP2A2 | c.1460A>G p.Q487R | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- APOL3 | c.1099del p.A367Qfs*9 (on ENST00000349314 / NM_145640.2; = p.A296Qfs*9 on NM_014349.3 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 45/194 reads (23%) | called by mutect2, pindel, varscan2
- APTX | c.163T>C p.Y55H | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ARHGAP17 | c.1151A>C p.K384T | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- ARHGAP27 | c.1030C>T p.P344S (on ENST00000428638 / NM_001282290.1; = p.P3S on NM_199282.3) | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- ARHGAP39 | c.3238G>A p.E1080K (on ENST00000276826 / NM_001308208.2; = p.E1111K on NM_025251.2) | Missense Mutation (SNP) | VAF 32/194 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- ARHGAP5 | c.2828del p.N943Ifs*2 | Frame Shift Del (DEL) | VAF 44/170 reads (26%) | called by mutect2, varscan2
- ASCC3 | c.2287-2A>G p.X763_splice | Splice Site (SNP) | VAF 56/388 reads (14%) | called by muse, mutect2, varscan2
- ASPH | c.1373del p.N458Mfs*9 | Frame Shift Del (DEL) | VAF 17/105 reads (16%) | called by mutect2, pindel, varscan2
- ASPH | c.903del p.P302Lfs*33 | Frame Shift Del (DEL) | VAF 10/81 reads (12%) | called by mutect2, pindel, varscan2
- ATG4A | c.373T>C p.C125R | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- ATN1 | c.1295_1296del p.L432Pfs*91 | Frame Shift Del (DEL) | VAF 25/122 reads (20%) | called by pindel, varscan2
- BAAT | c.1del p.M1? | Frame Shift Del (DEL) | VAF 30/170 reads (18%) | called by mutect2, varscan2
- BATF | c.203T>C p.L68P | Missense Mutation (SNP) | VAF 71/310 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BAZ1A | c.2750C>T p.A917V | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- BCAP31 | c.655C>A p.L219I | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- BNC2 | c.1487G>A p.R496H | Missense Mutation (SNP) | VAF 179/791 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- C2orf42 | c.1230del p.K410Nfs*38 | Frame Shift Del (DEL) | VAF 7/46 reads (15%) | called by mutect2, pindel, varscan2
- CACNA2D1 | c.2450A>G p.D817G (on ENST00000356253 / NM_001366867.1; = p.D805G on NM_000722.4) | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CADM4 | c.962T>C p.V321A | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- CASQ1 | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 49/280 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CBARP | c.155dup p.T53Hfs*78 (on ENST00000382477; = p.T59Hfs*78 on NM_152769.3) | Frame Shift Ins (INS) | VAF 29/129 reads (22%) | called by mutect2, pindel, varscan2
- CBWD1 | c.300G>A p.W100* | Nonsense Mutation (SNP) | VAF 24/169 reads (14%) | called by muse, mutect2, varscan2
- CBX4 | c.1144C>T p.H382Y | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- CCDC154 | c.1424G>A p.G475D | Missense Mutation (SNP) | VAF 12/249 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.26); called by muse, mutect2
- CCDC40 | c.418G>T p.G140C | Missense Mutation (SNP) | VAF 41/195 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- CD4 | c.686T>C p.V229A | Missense Mutation (SNP) | VAF 41/182 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD9 | c.200G>T p.G67V | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDC25C | c.931G>C p.A311P | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CDC42BPA | c.3817C>A p.L1273I (on ENST00000334218 / NM_001366019.2; = p.L1260I on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.96); called by muse, mutect2
- CDCA8 | c.548A>G p.K183R | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- CDH10 | c.1920del p.E641Sfs*3 | Frame Shift Del (DEL) | VAF 48/255 reads (19%) | called by pindel, varscan2
- CELSR2 | c.4532G>T p.G1511V | Missense Mutation (SNP) | VAF 39/168 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.02); called by mutect2, varscan2
- CELSR3 | c.1344G>T p.E448D | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- CEP120 | c.788T>C p.L263P | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CEP44 | c.1123del p.M375Cfs*9 | Frame Shift Del (DEL) | VAF 7/56 reads (13%) | called by mutect2, pindel
- CHD6 | c.4697G>T p.R1566M | Missense Mutation (SNP) | VAF 74/352 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); called by mutect2, varscan2
- CHMP3 | c.334A>G p.K112E | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.337); called by muse, mutect2, varscan2
- CHRD | c.2632T>C p.W878R | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- CLASP1 | c.4238C>T p.T1413I | Missense Mutation (SNP) | VAF 38/172 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- CLOCK | c.1128A>G p.V376= | Splice Region (SNP) | VAF 23/125 reads (18%) | called by muse, mutect2, varscan2
- CMTM3 | c.407G>A p.G136D | Missense Mutation (SNP) | VAF 73/403 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CMYA5 | c.8371T>A p.S2791T | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.046); called by muse, mutect2
- CPEB4 | c.2008T>C p.C670R | Missense Mutation (SNP) | VAF 25/169 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSF2RB | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 116/544 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- CSF3R | c.1831A>G p.S611G | Missense Mutation (SNP) | VAF 130/690 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0); called by mutect2, varscan2
- CTCF | c.610del p.T204Qfs*18 | Frame Shift Del (DEL) | VAF 36/196 reads (18%) | called by mutect2, varscan2
- CTR9 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- CTSS | c.627G>T p.M209I | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- CWC25 | c.275T>A p.I92N | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- DAAM2 | c.2253-5T>C | Splice Region (SNP) | VAF 26/188 reads (14%) | called by muse, varscan2
- DACT1 | c.687_688insT p.G230Wfs*13 | Frame Shift Ins (INS) | VAF 46/234 reads (20%) | called by mutect2, pindel, varscan2
- DBR1 | c.1071G>A p.M357I | Missense Mutation (SNP) | VAF 96/402 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.03); called by muse, varscan2
- DCAF7 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 49/204 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- DCHS2 | c.632A>G p.D211G | Missense Mutation (SNP) | VAF 116/459 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DDX39B | c.447del p.F149Lfs*13 | Frame Shift Del (DEL) | VAF 14/96 reads (15%) | called by mutect2, varscan2
- DDX49 | c.1352T>C p.L451P | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- DENND2B | c.491T>C p.I164T | Missense Mutation (SNP) | VAF 83/366 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- DERPC | c.1032T>A p.N344K | Missense Mutation (SNP) | VAF 49/212 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- DGCR2 | c.281C>A p.P94H | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- DGKZ | c.301del p.A101Pfs*10 | Frame Shift Del (DEL) | VAF 30/183 reads (16%) | called by mutect2, pindel, varscan2
- DGKZ | c.3110del p.P1037Qfs*38 (on ENST00000454345 / NM_001105540.2; = p.P849Qfs*38 on NM_003646.4) | Frame Shift Del (DEL) | VAF 23/120 reads (19%) | called by mutect2, varscan2
- DICER1 | c.980G>A p.R327K | Missense Mutation (SNP) | VAF 46/329 reads (14%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- DLGAP3 | c.2917C>T p.P973S | Missense Mutation (SNP) | VAF 52/235 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DLL1 | c.143del p.G48Afs*75 | Frame Shift Del (DEL) | VAF 63/376 reads (17%) | called by mutect2, pindel, varscan2
- DNAH1 | c.9400C>T p.Q3134* | Nonsense Mutation (SNP) | VAF 61/275 reads (22%) | called by muse, mutect2, varscan2
- DNAH7 | c.3466C>T p.H1156Y | Missense Mutation (SNP) | VAF 37/167 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- DNAJC2 | c.183G>T p.E61D | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- DNM3 | c.2293C>T p.H765Y (on ENST00000355305 / NM_001350206.2; = p.H759Y on NM_015569.5) | Missense Mutation (SNP) | VAF 42/382 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- DPH7 | c.680T>C p.V227A | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2
- EBF3 | c.833del p.G278Vfs*6 (on ENST00000355311 / NM_001375392.1; = p.G269Vfs*6 on NM_001005463.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 20/143 reads (14%) | called by mutect2, pindel, varscan2
- EDEM3 | c.2717A>G p.K906R | Missense Mutation (SNP) | VAF 66/357 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EEF1AKNMT | c.482T>G p.L161R (on ENST00000361735 / NM_015935.5; = p.L75R on NM_014955.3) | Missense Mutation (SNP) | VAF 133/833 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EFR3B | c.439A>G p.S147G | Missense Mutation (SNP) | VAF 47/250 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- EIF3J | c.419A>G p.N140S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- EMILIN1 | c.1787G>T p.R596L | Missense Mutation (SNP) | VAF 58/309 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- EPHX2 | c.548del p.L183Wfs*8 | Frame Shift Del (DEL) | VAF 17/85 reads (20%) | called by mutect2, pindel, varscan2
- EPPK1 | c.1070T>C p.L357P | Missense Mutation (SNP) | VAF 67/373 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- ERC1 | c.1282G>C p.V428L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2
- ERICH6 | c.1129del p.T377Qfs*15 | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | called by mutect2, pindel, varscan2
- FAHD2A | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 95/485 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- FAM241B | c.134dup p.P46Sfs*21 | Frame Shift Ins (INS) | VAF 55/227 reads (24%) | called by mutect2, pindel, varscan2
- FANCD2OS | c.392G>A p.S131N | Missense Mutation (SNP) | VAF 74/358 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FASTKD2 | c.445A>G p.T149A | Missense Mutation (SNP) | VAF 97/433 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAT3 | c.9777del p.F3259Lfs*52 | Frame Shift Del (DEL) | VAF 50/368 reads (14%) | called by mutect2, pindel, varscan2
- FBLN5 | c.1216A>G p.M406V | Missense Mutation (SNP) | VAF 129/533 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FBXL2 | c.983A>T p.D328V | Missense Mutation (SNP) | VAF 16/397 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.241); called by muse, mutect2
- FBXW11 | c.218_219del p.K73Rfs*5 | Frame Shift Del (DEL) | VAF 17/100 reads (17%) | called by mutect2, pindel, varscan2
- FCGBP | c.5215G>A p.A1739T | Missense Mutation (SNP) | VAF 34/367 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- FITM2 | c.608T>C p.V203A | Missense Mutation (SNP) | VAF 83/457 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- FOXG1 | c.617G>A p.G206D | Missense Mutation (SNP) | VAF 78/480 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- FOXG1 | c.793T>C p.F265L | Missense Mutation (SNP) | VAF 122/426 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- FPGS | c.1411C>T p.Q471* | Nonsense Mutation (SNP) | VAF 21/90 reads (23%) | called by muse, mutect2, varscan2
- FREM1 | c.3667A>G p.S1223G | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, varscan2
- FRMPD1 | c.2828C>T p.A943V | Missense Mutation (SNP) | VAF 87/424 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- FSIP2 | c.5623del p.S1875Qfs*40 | Frame Shift Del (DEL) | VAF 47/171 reads (27%) | called by mutect2, varscan2
- FZD2 | c.1202T>C p.V401A | Missense Mutation (SNP) | VAF 19/246 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- GABBR2 | c.142del p.R48Gfs*67 | Frame Shift Del (DEL) | VAF 7/38 reads (18%) | called by mutect2, pindel
- GAGE12G | c.87C>A p.P29= | Splice Region (SNP) | VAF 18/167 reads (11%) | called by mutect2, varscan2
- GANAB | c.2740C>A p.R914S | Missense Mutation (SNP) | VAF 49/164 reads (30%) | SIFT tolerated (0.93); PolyPhen benign (0); called by mutect2, varscan2
- GFOD1 | c.133_135del p.E45del | In Frame Del (DEL) | VAF 77/210 reads (37%) | called by mutect2, pindel, varscan2
- GGN | c.1583A>G p.N528S | Missense Mutation (SNP) | VAF 76/276 reads (28%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- GJC2 | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- GNB2 | c.253T>C p.Y85H | Missense Mutation (SNP) | VAF 51/228 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GPC1 | c.1444+2T>C p.X482_splice | Splice Site (SNP) | VAF 40/169 reads (24%) | called by muse, mutect2, varscan2
- GPRASP1 | c.2132G>A p.R711K | Missense Mutation (SNP) | VAF 81/397 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GTF2H2C | c.171+2T>C p.X57_splice | Splice Site (SNP) | VAF 8/58 reads (14%) | called by muse, mutect2
- H2BC21 | c.149A>G p.H50R | Missense Mutation (SNP) | VAF 38/247 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- H2BC7 | c.16A>G p.K6E | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); called by muse, mutect2
- HCN3 | c.1001T>C p.V334A | Missense Mutation (SNP) | VAF 44/310 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.158); called by muse, varscan2
- HDAC2 | c.300T>A p.D100E | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HEATR3 | c.1448G>A p.G483E | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HEATR5A | c.5599C>A p.L1867I | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- HECA | c.1132del p.E378Kfs*19 | Frame Shift Del (DEL) | VAF 78/457 reads (17%) | called by mutect2, pindel, varscan2
- HIPK2 | c.1304del p.F435Sfs*14 | Frame Shift Del (DEL) | VAF 22/125 reads (18%) | called by mutect2, pindel, varscan2
- HJV | c.44G>A p.G15D | Missense Mutation (SNP) | VAF 64/399 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- HNRNPAB | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- HPS4 | c.1133A>G p.Q378R | Missense Mutation (SNP) | VAF 151/640 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HPS5 | c.2285A>G p.D762G (on ENST00000349215 / NM_181507.2; = p.D648G on NM_007216.4) | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- HSPA4L | c.1526A>G p.D509G | Missense Mutation (SNP) | VAF 42/282 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- HTR1B | c.74T>C p.L25S | Missense Mutation (SNP) | VAF 106/446 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- IGSF22 | c.1411A>G p.K471E | Missense Mutation (SNP) | VAF 77/428 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- IL10RA | c.193G>T p.G65* | Nonsense Mutation (SNP) | VAF 118/504 reads (23%) | called by mutect2, varscan2
- ILF2 | c.349C>A p.H117N | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.123); called by muse, mutect2
- INPP1 | c.113_114del p.E38Gfs*10 | Frame Shift Del (DEL) | VAF 50/218 reads (23%) | called by pindel, varscan2
- INTS6 | c.340G>A p.G114R | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- IQGAP3 | c.25G>T p.G9C | Missense Mutation (SNP) | VAF 27/224 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- IRAK1 | c.1872C>A p.D624E | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT tolerated (0.98); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITGAE | c.1447T>C p.Y483H | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ITGAL | c.488G>T p.G163V | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITPR2 | c.2532A>T p.E844D | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- JADE3 | c.1421A>G p.H474R | Missense Mutation (SNP) | VAF 20/336 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); called by muse, mutect2
- JAKMIP1 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 140/655 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- KAT14 | c.1787G>A p.R596Q | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KCNJ9 | c.845C>T p.A282V | Missense Mutation (SNP) | VAF 46/380 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- KIAA1217 | c.2898+2T>C p.X966_splice | Splice Site (SNP) | VAF 22/136 reads (16%) | called by muse, mutect2
- KIAA1958 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 16/267 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- KIF24 | c.3545A>G p.D1182G | Missense Mutation (SNP) | VAF 56/299 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF7 | c.2446C>A p.Q816K | Missense Mutation (SNP) | VAF 22/536 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- KLC4 | c.76A>T p.T26S | Missense Mutation (SNP) | VAF 55/345 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- KLHL3 | c.713A>G p.H238R | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- KLHL33 | c.235T>C p.F79L | Missense Mutation (SNP) | VAF 20/392 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- KNG1 | c.1201A>G p.T401A | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.374); called by muse, mutect2
- KNTC1 | c.3258del p.K1086Nfs*20 | Frame Shift Del (DEL) | VAF 16/69 reads (23%) | called by mutect2, pindel, varscan2
- KRT4 | c.146G>A p.S49N | Missense Mutation (SNP) | VAF 37/186 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- LARS1 | c.1837G>A p.G613S (on ENST00000394434 / NM_020117.11; = p.G586S on NM_016460.3) | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- LCA5L | c.1726C>T p.P576S | Missense Mutation (SNP) | VAF 61/288 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LDHB | c.629T>C p.V210A | Missense Mutation (SNP) | VAF 39/178 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, varscan2
- LINGO3 | c.864del p.S289Rfs*53 | Frame Shift Del (DEL) | VAF 36/168 reads (21%) | called by mutect2, pindel, varscan2
- LMBRD1 | c.464T>C p.L155P | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- LRP3 | c.2255del p.P752Rfs*26 | Frame Shift Del (DEL) | VAF 21/111 reads (19%) | called by mutect2, varscan2
- LRRC71 | c.887del p.G296Afs*3 | Frame Shift Del (DEL) | VAF 63/399 reads (16%) | called by mutect2, pindel, varscan2
- LSM2 | c.177C>A p.N59K | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2
- MAK16 | c.640-2A>G p.X214_splice | Splice Site (SNP) | VAF 6/34 reads (18%) | called by muse, varscan2
- MAP7D1 | c.1628C>T p.A543V | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MARF1 | c.1951C>T p.Q651* | Nonsense Mutation (SNP) | VAF 18/75 reads (24%) | called by muse, mutect2, varscan2
- MDN1 | c.4922A>G p.Y1641C | Missense Mutation (SNP) | VAF 12/298 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2
- MFSD4A | c.1159G>A p.V387M | Missense Mutation (SNP) | VAF 38/219 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- MPIG6B | c.17A>G p.Q6R | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- MRGPRX1 | c.310T>C p.F104L | Missense Mutation (SNP) | VAF 59/338 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- MTOR | c.5963A>G p.H1988R | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT tolerated (0.87); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MTTP | c.650T>C p.V217A | Missense Mutation (SNP) | VAF 53/332 reads (16%) | SIFT tolerated (0.95); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MTX1 | c.784del p.W262Gfs*2 | Frame Shift Del (DEL) | VAF 42/304 reads (14%) | called by mutect2, varscan2
- MUC17 | c.2081C>A p.P694H | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.099); called by mutect2, varscan2
- MYBL1 | c.1259del p.N420Tfs*13 | Frame Shift Del (DEL) | VAF 22/136 reads (16%) | called by mutect2, varscan2
- MYO15B | c.6739C>T p.Q2247* | Nonsense Mutation (SNP) | VAF 19/75 reads (25%) | called by muse, mutect2, varscan2
- MYOF | c.5968C>T p.P1990S | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NACC2 | c.1333C>T p.R445C | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- NAV3 | c.516dup p.L173Sfs*62 | Frame Shift Ins (INS) | VAF 18/94 reads (19%) | called by mutect2, pindel, varscan2
- NBN | c.1651del p.R551Gfs*8 | Frame Shift Del (DEL) | VAF 47/302 reads (16%) | called by mutect2, pindel, varscan2
- NBPF12 | c.1922T>C p.V641A | Missense Mutation (SNP) | VAF 20/552 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.68); called by muse, mutect2
- NEK2 | c.891G>T p.Q297H | Missense Mutation (SNP) | VAF 26/212 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.179); called by mutect2, varscan2
- NFASC | c.712G>T p.G238* (on ENST00000339876 / NM_001378329.1; = p.G249* on NM_015090.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 28/187 reads (15%) | called by muse, mutect2, varscan2
- NFKB2 | c.879del p.Y294Ifs*4 | Frame Shift Del (DEL) | VAF 23/96 reads (24%) | called by mutect2, pindel, varscan2
- NKAIN2 | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 32/252 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, varscan2
- NMUR1 | c.1231del p.L411Wfs*55 | Frame Shift Del (DEL) | VAF 39/208 reads (19%) | called by mutect2, pindel, varscan2
- NOL6 | c.2857del p.Q953Kfs*32 | Frame Shift Del (DEL) | VAF 22/73 reads (30%) | called by mutect2, pindel
- NOMO3 | c.595G>A p.V199M | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- NPC1 | c.1877T>G p.I626S | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.22); called by muse, mutect2
- NPTX1 | c.448T>C p.Y150H | Missense Mutation (SNP) | VAF 20/302 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2
- NRXN2 | c.2549G>A p.G850E | Missense Mutation (SNP) | VAF 19/234 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- NSUN6 | c.327del p.K109Nfs*17 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | called by pindel, varscan2
- NTNG2 | c.466G>T p.D156Y | Missense Mutation (SNP) | VAF 106/530 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- OBSCN | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 77/413 reads (19%) | SIFT tolerated (0.8); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OMA1 | c.904-1G>A p.X302_splice | Splice Site (SNP) | VAF 25/94 reads (27%) | called by muse, mutect2, varscan2
- OR1Q1 | c.827T>C p.V276A | Missense Mutation (SNP) | VAF 55/222 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.565); called by muse, mutect2, varscan2
- OR5V1 | c.443G>A p.C148Y | Missense Mutation (SNP) | VAF 85/437 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- P3H4 | c.1063-7C>T | Splice Region (SNP) | VAF 21/99 reads (21%) | called by muse, mutect2, varscan2
- PAPLN | c.569A>G p.D190G | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- PCDH7 | c.3051del p.K1017Nfs*110 | Frame Shift Del (DEL) | VAF 40/214 reads (19%) | called by mutect2, pindel, varscan2
- PFN2 | c.271_272del p.K91Efs*17 | Frame Shift Del (DEL) | VAF 27/146 reads (18%) | called by mutect2, pindel, varscan2
- PHACTR1 | c.1366C>T p.Q456* | Nonsense Mutation (SNP) | VAF 41/299 reads (14%) | called by muse, mutect2, varscan2
- PHKG2 | c.913del p.R305Afs*19 | Frame Shift Del (DEL) | VAF 186/778 reads (24%) | called by mutect2, varscan2
- PIEZO2 | c.6011del p.P2004Qfs*4 | Frame Shift Del (DEL) | VAF 15/82 reads (18%) | called by mutect2, pindel, varscan2
- PIGC | c.825del p.F275Lfs*32 | Frame Shift Del (DEL) | VAF 22/130 reads (17%) | called by mutect2, pindel
- PIGW | c.844A>G p.K282E | Missense Mutation (SNP) | VAF 71/306 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- PITPNM3 | c.1340T>C p.L447P | Missense Mutation (SNP) | VAF 131/573 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PKHD1 | c.9585del p.V3196Cfs*24 | Frame Shift Del (DEL) | VAF 167/997 reads (17%) | called by mutect2, pindel, varscan2
- PLCE1 | c.1899A>C p.K633N | Missense Mutation (SNP) | VAF 88/380 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PLCE1 | c.3721G>A p.A1241T | Missense Mutation (SNP) | VAF 44/1036 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.309); called by muse, mutect2
- PNPLA7 | c.672+2T>C p.X224_splice | Splice Site (SNP) | VAF 29/144 reads (20%) | called by muse, mutect2, varscan2
- POGZ | c.3405G>T p.E1135D | Missense Mutation (SNP) | VAF 83/562 reads (15%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- POLD3 | c.717dup p.G240Wfs*7 | Frame Shift Ins (INS) | VAF 17/73 reads (23%) | called by mutect2, pindel, varscan2
- PQBP1 | c.640del p.R214Gfs*62 | Frame Shift Del (DEL) | VAF 74/392 reads (19%) | called by mutect2, pindel, varscan2
- PRLHR | c.1078dup p.H360Pfs*47 | Frame Shift Ins (INS) | VAF 11/71 reads (15%) | called by mutect2, pindel
- PRLHR | c.320T>C p.V107A | Missense Mutation (SNP) | VAF 136/490 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.567); called by mutect2, varscan2
- PRMT8 | c.1054del p.E352Rfs*9 | Frame Shift Del (DEL) | VAF 13/63 reads (21%) | called by mutect2, pindel, varscan2
- PRPSAP2 | c.922del p.R308Gfs*36 | Frame Shift Del (DEL) | VAF 62/309 reads (20%) | called by mutect2, varscan2
- PRR7 | c.209dup p.L72Pfs*11 | Frame Shift Ins (INS) | VAF 22/91 reads (24%) | called by mutect2, pindel, varscan2
- PRSS36 | c.2031G>C p.R677S | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- PTBP1 | c.553A>G p.R185G | Missense Mutation (SNP) | VAF 46/198 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- PTBP3 | c.601-2del p.X201_splice | Splice Site (DEL) | VAF 13/42 reads (31%) | called by mutect2, pindel, varscan2
- PTPRS | c.3379A>G p.S1127G | Missense Mutation (SNP) | VAF 87/404 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- RAI1 | c.4306C>T p.Q1436* | Nonsense Mutation (SNP) | VAF 93/464 reads (20%) | called by mutect2, varscan2
- RARG | c.628T>C p.Y210H | Missense Mutation (SNP) | VAF 41/157 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RB1CC1 | c.835A>G p.R279G | Missense Mutation (SNP) | VAF 61/430 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RBFA | c.817A>G p.T273A | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNF126 | c.679C>A p.L227I | Missense Mutation (SNP) | VAF 42/158 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- RNF130 | c.652A>G p.I218V | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.347); called by muse, mutect2
- RNF4 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RNF8 | c.440del p.N147Ifs*4 | Frame Shift Del (DEL) | VAF 46/166 reads (28%) | called by mutect2, pindel, varscan2
- RORA | c.679C>T p.P227S (on ENST00000335670 / NM_134261.3; = p.P252S on NM_002943.3) | Missense Mutation (SNP) | VAF 42/220 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- RP1L1 | c.4114del p.V1372Cfs*3 | Frame Shift Del (DEL) | VAF 46/374 reads (12%) | called by mutect2, pindel, varscan2
- RPA1 | c.1645dup p.E549Gfs*7 | Frame Shift Ins (INS) | VAF 6/49 reads (12%) | called by mutect2, varscan2
- RPL7L1 | c.449+6_449+9del p.X150_splice | Splice Site (DEL) | VAF 30/135 reads (22%) | called by pindel, varscan2
- RTL9 | c.2051T>C p.M684T | Missense Mutation (SNP) | VAF 131/581 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.586); called by muse, mutect2, varscan2
- S1PR1 | c.539T>C p.M180T | Missense Mutation (SNP) | VAF 162/728 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- SACS | c.13001T>C p.L4334S | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SAMSN1 | c.208del p.M70* | Frame Shift Del (DEL) | VAF 11/70 reads (16%) | called by mutect2, pindel, varscan2
- SBF2 | c.611A>T p.Q204L | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.101); called by muse, varscan2
- SCN7A | c.3367del p.M1123* | Frame Shift Del (DEL) | VAF 32/128 reads (25%) | called by mutect2, pindel, varscan2
- SCUBE3 | c.2263T>C p.Y755H | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SEC24D | c.1707G>T p.K569N | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SEC61A2 | c.1285G>T p.G429C | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SELENOM | c.221A>G p.H74R | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- SETD1B | c.4342T>C p.C1448R | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- SF3B4 | c.1060del p.R354Efs*26 | Frame Shift Del (DEL) | VAF 7/67 reads (10%) | called by pindel, varscan2
- SI | c.1107A>C p.K369N | Missense Mutation (SNP) | VAF 69/318 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- SIK2 | c.2486del p.P829Lfs*49 | Frame Shift Del (DEL) | VAF 37/174 reads (21%) | called by mutect2, pindel, varscan2
- SLC26A5 | c.169del p.I57* | Frame Shift Del (DEL) | VAF 34/221 reads (15%) | called by mutect2, pindel, varscan2
- SLC41A2 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.028); called by muse, varscan2
- SLC45A3 | c.1558G>A p.V520I | Missense Mutation (SNP) | VAF 98/613 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SLC6A1 | c.427A>G p.I143V | Missense Mutation (SNP) | VAF 38/224 reads (17%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.997); called by muse, varscan2
- SLC9A1 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- SMAD3 | c.545del p.P182Lfs*4 | Frame Shift Del (DEL) | VAF 116/498 reads (23%) | called by mutect2, varscan2
- SMAD5 | c.1208T>C p.V403A | Missense Mutation (SNP) | VAF 22/370 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.042); called by muse, mutect2
- SMS | c.28G>T p.D10Y | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, varscan2
- SMU1 | c.1265T>C p.V422A | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SNX27 | c.666G>T p.K222N | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SORT1 | c.970A>G p.T324A | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- SPAG17 | c.3329A>G p.D1110G | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- SPAG17 | c.1496del p.K499Rfs*25 | Frame Shift Del (DEL) | VAF 60/279 reads (22%) | called by mutect2, pindel, varscan2
- SPAG6 | c.1374del p.V459Ffs*4 | Frame Shift Del (DEL) | VAF 8/58 reads (14%) | called by mutect2, pindel, varscan2
- SPHKAP | c.1677T>A p.C559* | Nonsense Mutation (SNP) | VAF 120/550 reads (22%) | called by muse, mutect2, varscan2
- SPNS2 | c.412C>T p.R138* | Nonsense Mutation (SNP) | VAF 20/148 reads (14%) | called by muse, mutect2, varscan2
- SRCIN1 | c.45del p.M16Cfs*44 | Frame Shift Del (DEL) | VAF 40/155 reads (26%) | called by mutect2, varscan2
- SRGAP1 | c.2327C>T p.A776V | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- STARD9 | c.5027G>T p.R1676M | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- STIM2 | c.1529G>A p.S510N | Missense Mutation (SNP) | VAF 52/244 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- STRN4 | c.1720dup p.S574Kfs*46 | Frame Shift Ins (INS) | VAF 61/234 reads (26%) | called by mutect2, pindel, varscan2
- SULF2 | c.2468A>G p.N823S | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- SV2A | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 107/806 reads (13%) | SIFT tolerated (0.79); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SYCE2 | c.80A>G p.H27R | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- SYVN1 | c.1186C>A p.P396T | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- TAS2R10 | c.292T>C p.F98L | Missense Mutation (SNP) | VAF 56/254 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- TAX1BP1 | c.79C>T p.L27F | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- TBC1D14 | c.1629del p.F543Lfs*9 | Frame Shift Del (DEL) | VAF 29/116 reads (25%) | called by mutect2, pindel, varscan2
- TBC1D19 | c.1560del p.L521Cfs*17 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | called by mutect2, pindel, varscan2
- TBC1D32 | c.3113T>A p.L1038* | Nonsense Mutation (SNP) | VAF 17/92 reads (18%) | called by muse, mutect2, varscan2
- TBXA2R | c.834dup p.A279Rfs*112 | Frame Shift Ins (INS) | VAF 51/268 reads (19%) | called by mutect2, pindel, varscan2
- TCF4 | c.120del p.F40Lfs*8 | Frame Shift Del (DEL) | VAF 18/123 reads (15%) | called by mutect2, pindel, varscan2
- TCTE1 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 17/434 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.631); called by muse, mutect2
- TDRD3 | c.131del p.N44Mfs*6 | Frame Shift Del (DEL) | VAF 32/199 reads (16%) | called by mutect2, pindel, varscan2
- TEX50 | c.286C>T p.H96Y | Missense Mutation (SNP) | VAF 24/213 reads (11%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- TFAP2B | c.219del p.Y74Tfs*22 | Frame Shift Del (DEL) | VAF 22/116 reads (19%) | called by mutect2, pindel
- TFDP1 | c.252del p.S85Afs*37 | Frame Shift Del (DEL) | VAF 31/250 reads (12%) | called by mutect2, pindel, varscan2
- TFE3 | c.1445del p.G482Dfs*44 | Frame Shift Del (DEL) | VAF 56/156 reads (36%) | called by mutect2, varscan2
- TIGD3 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TIGD3 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 56/239 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TJP1 | c.142G>A p.G48S | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated, low confidence (0.51); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- TMEM131L | c.1742del p.L581Cfs*4 | Frame Shift Del (DEL) | VAF 6/43 reads (14%) | called by mutect2, pindel, varscan2
- TMEM214 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 59/273 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.37); called by muse, mutect2, varscan2
- TMPRSS7 | c.671T>C p.M224T (on ENST00000452346; = p.M111T on NM_001042575.2) | Missense Mutation (SNP) | VAF 34/190 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- TNFSF13 | c.59del p.G20Afs*14 | Frame Shift Del (DEL) | VAF 20/71 reads (28%) | called by mutect2, varscan2
- TNRC6C | c.1615dup p.D539Gfs*9 | Frame Shift Ins (INS) | VAF 6/33 reads (18%) | called by mutect2, pindel
- TONSL | c.1489A>G p.T497A | Missense Mutation (SNP) | VAF 84/424 reads (20%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, varscan2
- TOP1MT | c.1291T>C p.S431P | Missense Mutation (SNP) | VAF 34/205 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TPRG1L | c.782T>C p.L261P | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRAK1 | c.2417A>G p.Y806C | Missense Mutation (SNP) | VAF 158/701 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TRAPPC13 | c.758A>T p.Y253F | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- TRIM14 | c.1282G>A p.A428T | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIM24 | c.2903A>G p.D968G (on ENST00000343526 / NM_015905.3; = p.D934G on NM_003852.4) | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRPM1 | c.2277del p.T760Pfs*110 | Frame Shift Del (DEL) | VAF 81/318 reads (25%) | called by mutect2, pindel, varscan2
- TRPM3 | c.2953T>C p.Y985H (on ENST00000357533 / NM_001366142.2; = p.Y828H on NM_020952.6) | Missense Mutation (SNP) | VAF 38/200 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TRPM4 | c.3436G>A p.E1146K | Missense Mutation (SNP) | VAF 62/319 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- TRPV6 | c.469+2T>C p.X157_splice | Splice Site (SNP) | VAF 36/165 reads (22%) | called by muse, mutect2, varscan2
- TSPAN1 | c.95T>C p.V32A | Missense Mutation (SNP) | VAF 117/531 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- TTC17 | c.3173C>T p.A1058V | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TTC34 | c.2765C>T p.A922V | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TTN | c.87352A>T p.R29118* (on ENST00000591111; = p.R21694* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 22/392 reads (6%) | called by muse, mutect2
- TTN | c.36097T>C p.F12033L (on ENST00000591111; = p.F4609L on NM_003319.4) | Missense Mutation (SNP) | VAF 49/212 reads (23%) | PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- UBA52 | c.49G>C p.V17L | Missense Mutation (SNP) | VAF 38/213 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- UBE2T | c.286-2A>T p.X96_splice | Splice Site (SNP) | VAF 30/201 reads (15%) | called by muse, mutect2, varscan2
- UBE4A | c.523del p.C175Vfs*56 | Frame Shift Del (DEL) | VAF 20/110 reads (18%) | called by mutect2, pindel, varscan2
- USP1 | c.451T>C p.S151P | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- UTP4 | c.974C>T p.A325V | Missense Mutation (SNP) | VAF 77/414 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- VIRMA | c.554C>A p.P185H | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VPS35L | c.1168T>G p.L390V | Missense Mutation (SNP) | VAF 68/330 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- WDFY3 | c.10102del p.H3368Tfs*13 | Frame Shift Del (DEL) | VAF 30/210 reads (14%) | called by mutect2, varscan2
- WDFY3 | c.4694C>T p.A1565V | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR13 | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- WDR31 | c.5T>C p.L2P | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- WDTC1 | c.565T>A p.C189S | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- WIZ | c.5170G>A p.G1724R (on ENST00000673675 / NM_001371589.1; = p.G629R on NM_021241.3) | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); called by muse, mutect2
- WNK2 | c.2809G>A p.A937T | Missense Mutation (SNP) | VAF 43/235 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- WNK3 | c.1215dup p.A406Cfs*2 | Frame Shift Ins (INS) | VAF 32/159 reads (20%) | called by mutect2, pindel, varscan2
- WNT6 | c.950T>C p.L317P | Missense Mutation (SNP) | VAF 39/286 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- XAGE5 | c.179-4del | Splice Region (DEL) | VAF 14/77 reads (18%) | called by mutect2, pindel, varscan2
- XKR5 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 96/655 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- XYLT2 | c.1008-1G>A p.X336_splice | Splice Site (SNP) | VAF 19/79 reads (24%) | called by muse, mutect2, varscan2
- ZBTB20 | c.2075del p.P692Lfs*43 (on ENST00000474710 / NM_001164342.2; = p.P619Lfs*43 on NM_015642.6 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 54/259 reads (21%) | called by mutect2, varscan2
- ZBTB20 | c.176dup p.H59Qfs*8 | Frame Shift Ins (INS) | VAF 18/121 reads (15%) | called by mutect2, pindel, varscan2
- ZCCHC14 | c.634+2T>C p.X212_splice (on ENST00000268616; = p.X349_splice on NM_015144.3) | Splice Site (SNP) | VAF 12/39 reads (31%) | called by muse, varscan2
- ZFC3H1 | c.211G>A p.G71S | Missense Mutation (SNP) | VAF 112/544 reads (21%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.305); called by muse, varscan2
- ZFP64 | c.329A>G p.Y110C | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZFYVE28 | c.950del p.E317Gfs*142 | Frame Shift Del (DEL) | VAF 33/216 reads (15%) | called by mutect2, varscan2
- ZNF106 | c.1221del p.E408Kfs*22 | Frame Shift Del (DEL) | VAF 37/174 reads (21%) | called by mutect2, varscan2
- ZNF513 | c.683A>G p.H228R | Missense Mutation (SNP) | VAF 137/583 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZNF517 | c.809T>C p.F270S | Missense Mutation (SNP) | VAF 67/326 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF558 | c.862G>T p.G288W | Missense Mutation (SNP) | VAF 41/194 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- ZNF595 | c.1370G>A p.C457Y | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF630 | c.1321del p.C441Afs*7 | Frame Shift Del (DEL) | VAF 51/273 reads (19%) | called by mutect2, pindel, varscan2
- ZNF649 | c.1262A>G p.H421R | Missense Mutation (SNP) | VAF 21/539 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2
- ZNF687 | c.2327T>C p.V776A | Missense Mutation (SNP) | VAF 26/194 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- ZNF736 | c.1268A>G p.K423R | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF792 | c.241A>T p.T81S | Missense Mutation (SNP) | VAF 44/181 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- ZNF805 | c.620A>G p.E207G | Missense Mutation (SNP) | VAF 61/276 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- ZNF844 | c.568A>C p.M190L | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2
- ZSCAN2 | c.373G>A p.V125M | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.086); called by muse, mutect2
- ZSCAN5A | c.277A>G p.M93V | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.127); called by muse, mutect2
- ACTN1 | c.2463C>T p.A821= | Silent (SNP) | VAF 28/155 reads (18%) | catalogued as rs774599678, COSV51995693; called by muse, mutect2, varscan2
- ACTRT2 | c.801G>A p.Q267= | Silent (SNP) | VAF 61/336 reads (18%) | called by muse, mutect2, varscan2
- ACVR1B | c.966C>T p.I322= | Silent (SNP) | VAF 31/112 reads (28%) | catalogued as rs763203996, COSV57775230; called by muse, mutect2, varscan2
- ADA2 | c.357G>A p.V119= | Silent (SNP) | VAF 32/169 reads (19%) | called by muse, mutect2, varscan2
- ADAR | c.1077G>A p.K359= | Silent (SNP) | VAF 76/514 reads (15%) | called by muse, mutect2, varscan2
- ADGRL2 | c.3675G>A p.P1225= (on ENST00000370717 / NM_001366005.1; = p.P1169= on NM_012302.4) | Silent (SNP) | VAF 73/349 reads (21%) | catalogued as rs368910598; called by muse, mutect2, varscan2
- ADPRS | c.382C>T p.L128= | Silent (SNP) | VAF 29/125 reads (23%) | called by muse, mutect2, varscan2
- AGAP3 | c.2541C>T p.G847= (on ENST00000622464; = p.G883= on NM_031946.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 90/387 reads (23%) | called by muse, mutect2, varscan2
- ALDH3B2 | c.663C>T p.R221= | Silent (SNP) | VAF 38/150 reads (25%) | catalogued as rs80147122; called by muse, mutect2, varscan2
- ANK1 | c.2853C>T p.C951= | Silent (SNP) | VAF 46/884 reads (5%) | called by muse, mutect2
- ANKRD17 | c.6324G>A p.Q2108= | Silent (SNP) | VAF 123/518 reads (24%) | called by muse, mutect2, varscan2
- ANKRD46 | c.646C>T p.L216= | Silent (SNP) | VAF 13/87 reads (15%) | called by muse, mutect2, varscan2
- AOX1 | c.2541C>T p.G847= | Silent (SNP) | VAF 66/291 reads (23%) | catalogued as rs34799295; called by muse, mutect2, varscan2
- AP1G2 | c.2112A>C p.S704= | Silent (SNP) | VAF 44/206 reads (21%) | catalogued as COSV99846048; called by muse, mutect2, varscan2
- APAF1 | c.1626G>A p.E542= (on ENST00000551964 / NM_181861.2; = p.E531= on NM_001160.3) | Silent (SNP) | VAF 33/132 reads (25%) | called by muse, mutect2, varscan2
- ARHGAP30 | c.2898G>A p.P966= (on ENST00000368013 / NM_001025598.2; = p.P755= on NM_181720.3) | Silent (SNP) | VAF 52/376 reads (14%) | catalogued as COSV100920331; called by muse, mutect2, varscan2
- ARHGAP4 | c.336G>A p.Q112= | Silent (SNP) | VAF 35/160 reads (22%) | called by muse, mutect2, varscan2
- ARL13A | c.444T>C p.L148= | Silent (SNP) | VAF 15/61 reads (25%) | called by muse, mutect2, varscan2
- ARMC5 | c.2643T>C p.A881= | Silent (SNP) | VAF 21/123 reads (17%) | called by muse, mutect2, varscan2
- ASTN1 | c.2877T>C p.V959= | Silent (SNP) | VAF 70/449 reads (16%) | called by muse, mutect2, varscan2
- ATP11B | c.243T>C p.I81= | Silent (SNP) | VAF 5/81 reads (6%) | called by muse, mutect2
- ATP13A2 | c.366G>A p.Q122= | Silent (SNP) | VAF 108/518 reads (21%) | catalogued as COSV58699147; called by muse, varscan2
- ATP13A5 | c.951T>C p.S317= | Silent (SNP) | VAF 29/168 reads (17%) | catalogued as rs1472073825, COSV60868430; called by muse, mutect2, varscan2
- ATP9B | c.363A>G p.G121= | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as rs1252511380; called by muse, mutect2, varscan2
- ATXN1 | c.2298C>T p.P766= | Silent (SNP) | VAF 64/363 reads (18%) | catalogued as rs1290816346; called by muse, mutect2, varscan2
- BAIAP3 | c.3237C>T p.Y1079= | Silent (SNP) | VAF 63/277 reads (23%) | catalogued as rs529900567; called by muse, mutect2, varscan2
- BCL11B | c.942G>A p.P314= (on ENST00000357195 / NM_001282237.2; = p.P243= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as rs1433890901, COSV61737429; called by muse, mutect2, varscan2
- BTBD11 | c.1353C>T p.T451= | Silent (SNP) | VAF 20/333 reads (6%) | called by muse, mutect2
- C2CD5 | c.2976A>G p.S992= | Silent (SNP) | VAF 16/85 reads (19%) | called by muse, mutect2, varscan2
- C4orf50 | c.801C>A p.V267= (on ENST00000324058; = p.V1499= on NM_001364689.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 38/172 reads (22%) | called by muse, mutect2, varscan2
- CADPS | c.1821C>T p.D607= | Silent (SNP) | VAF 31/197 reads (16%) | catalogued as rs528317538; called by muse, mutect2, varscan2
- CCDC59 | c.684A>G p.V228= | Silent (SNP) | VAF 33/118 reads (28%) | catalogued as rs138694550; called by muse, mutect2, varscan2
- CCM2 | c.768C>T p.D256= | Silent (SNP) | VAF 150/708 reads (21%) | called by muse, mutect2, varscan2
- CDCA5 | c.189G>A p.T63= | Silent (SNP) | VAF 20/98 reads (20%) | catalogued as rs1487011886; called by muse, varscan2
- CENPF | c.4215C>T p.A1405= | Silent (SNP) | VAF 25/167 reads (15%) | catalogued as rs541145038, COSV100871455; called by muse, mutect2, varscan2
- CES4A | c.1437C>T p.F479= (on ENST00000648724 / NM_001364782.1; = p.F381= on NM_001190201.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 33/136 reads (24%) | catalogued as rs752384228; called by muse, mutect2, varscan2
- CLCN5 | c.1413A>T p.V471= | Silent (SNP) | VAF 34/648 reads (5%) | called by muse, mutect2
- CLDN23 | c.750G>A p.P250= | Silent (SNP) | VAF 19/106 reads (18%) | catalogued as rs748969626; called by muse, mutect2, varscan2
- CLUH | c.2460G>A p.S820= (on ENST00000435359; = p.S859= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 57/274 reads (21%) | catalogued as rs771509448, COSV70928140; called by muse, mutect2, varscan2
- CNGA3 | c.835C>T p.L279= | Silent (SNP) | VAF 126/498 reads (25%) | called by muse, mutect2, varscan2
- COL12A1 | c.3606G>A p.L1202= | Silent (SNP) | VAF 73/421 reads (17%) | called by muse, mutect2, varscan2
- CPLANE1 | c.8205T>C p.C2735= | Silent (SNP) | VAF 20/93 reads (22%) | called by muse, mutect2, varscan2
- CPS1 | c.3459A>G p.E1153= | Silent (SNP) | VAF 24/416 reads (6%) | called by muse, mutect2
- CRY2 | c.1698C>A p.A566= | Silent (SNP) | VAF 25/112 reads (22%) | called by muse, mutect2, varscan2
- CTRB2 | c.447C>T p.P149= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as rs1162913457; called by mutect2, varscan2
- CUL3 | c.2196G>A p.A732= | Silent (SNP) | VAF 26/123 reads (21%) | catalogued as rs551278501; called by muse, mutect2, varscan2
- DAGLB | c.1701G>A p.T567= | Silent (SNP) | VAF 17/102 reads (17%) | catalogued as rs201711486; called by muse, mutect2, varscan2
- DBF4B | c.813C>T p.G271= | Silent (SNP) | VAF 15/89 reads (17%) | called by muse, mutect2, varscan2
- DCAF12L2 | c.907C>T p.L303= | Silent (SNP) | VAF 75/402 reads (19%) | called by muse, mutect2, varscan2
- DDI1 | c.1068G>A p.T356= | Silent (SNP) | VAF 97/442 reads (22%) | catalogued as rs760519987, COSV56391820; called by muse, mutect2, varscan2
- DGKQ | c.1440G>A p.R480= | Silent (SNP) | VAF 25/101 reads (25%) | called by muse, mutect2, varscan2
- DIAPH2 | c.693T>C p.Y231= | Silent (SNP) | VAF 20/81 reads (25%) | called by muse, mutect2, varscan2
- DLK1 | c.583C>A p.R195= | Silent (SNP) | VAF 49/212 reads (23%) | catalogued as COSV57991140; called by muse, varscan2
- DNAH10 | c.6345T>C p.G2115= (on ENST00000409039; = p.G2054= on NM_207437.3) | Silent (SNP) | VAF 14/68 reads (21%) | called by muse, mutect2, varscan2
- DNAJB11 | c.702G>T p.G234= | Silent (SNP) | VAF 14/79 reads (18%) | called by muse, mutect2, varscan2
- DOCK5 | c.1032T>C p.H344= | Silent (SNP) | VAF 7/44 reads (16%) | called by muse, mutect2
- DPYSL2 | c.1242C>T p.P414= | Silent (SNP) | VAF 24/120 reads (20%) | catalogued as rs756562073, COSV100233712, COSV100233943; called by muse, mutect2, varscan2
- DQX1 | c.297T>A p.T99= | Silent (SNP) | VAF 35/165 reads (21%) | called by muse, mutect2, varscan2
- DZIP1 | c.1434C>T p.A478= (on ENST00000347108; = p.A459= on NM_014934.5) | Silent (SNP) | VAF 13/63 reads (21%) | called by muse, mutect2, varscan2
- ECHDC3 | c.849G>A p.G283= | Silent (SNP) | VAF 34/152 reads (22%) | catalogued as rs762417319; called by muse, varscan2
- ECT2 | c.435T>C p.D145= (on ENST00000392692 / NM_001349098.2; = p.D114= on NM_018098.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as rs774280055; called by muse, mutect2, varscan2
- EIF3D | c.1479C>T p.C493= | Silent (SNP) | VAF 105/441 reads (24%) | catalogued as rs371162938, COSV53399035; called by muse, mutect2, varscan2
- EIF4A2 | c.1041T>C p.N347= | Silent (SNP) | VAF 39/168 reads (23%) | catalogued as COSV56218137; called by muse, mutect2, varscan2
- ELP3 | c.1554C>T p.I518= | Silent (SNP) | VAF 20/114 reads (18%) | catalogued as rs774307743, COSV56458943, COSV99834271; called by muse, mutect2, varscan2
- EML6 | c.4737C>T p.Y1579= | Silent (SNP) | VAF 35/106 reads (33%) | catalogued as rs1205218795; called by muse, mutect2, varscan2
- EPCAM | c.720G>A p.L240= | Silent (SNP) | VAF 61/255 reads (24%) | catalogued as rs565682940; called by muse, mutect2, varscan2
261 further variants in this file (0 protein-altering or splice-affecting, 126 silent, 135 other) are not listed here.
